Somatic mutation profile of tumor specimen 0D9Z2L from CCDI case PBBIXR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 8.3 years (3,020 days).
Specimen 0D9Z2L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7829b21-752d-424a-86b7-98360bbec918.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9Z2O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fce7bf1e-e913-42b8-9f52-22c1092cf641

The open-access MAF lists 52 somatic variants for this specimen: 40 protein-altering or splice-affecting, 4 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 4, 5'UTR 4, Intron 3, Frame Shift Del 2, Splice Site 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 312/963 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 197/238 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- C9orf85 | c.288C>G p.C96W | Missense Mutation (SNP) | VAF 267/1130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58253981; called by muse, mutect2, varscan2
- DBF4 | c.1109A>T p.E370V | Missense Mutation (SNP) | VAF 262/1318 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV99719557; called by muse, mutect2, varscan2
- DCAF12L2 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 196/462 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as COSV63580157; called by muse, mutect2, varscan2
- DOCK2 | c.760A>T p.S254C | Missense Mutation (SNP) | VAF 122/460 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56944625; called by muse, varscan2
- FLRT2 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs148371022, COSV58149138; called by muse, mutect2, varscan2
- HCK | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 115/483 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as rs767291366; called by muse, mutect2, varscan2
- HPS3 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 224/528 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.231); catalogued as rs143804526; called by muse, mutect2, varscan2
- LRRTM4 | c.1035C>G p.I345M | Missense Mutation (SNP) | VAF 75/620 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV101297416, COSV101297515; called by muse, mutect2, varscan2
- MAGEB6 | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 305/678 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1292155676; called by muse, mutect2, varscan2
- MYH2 | c.715G>C p.V239L | Missense Mutation (SNP) | VAF 139/244 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0.081); catalogued as COSV55433810; called by muse, mutect2, varscan2
- OGDHL | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 184/418 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs752996866; called by muse, mutect2, varscan2
- OR4P4 | c.291A>G p.I97M | Missense Mutation (SNP) | VAF 106/229 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1171972926, COSV58920874; called by muse, mutect2, varscan2
- RIMS2 | c.838C>T p.H280Y (on ENST00000666250 / NM_001348490.2; = p.H88Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 139/341 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); catalogued as COSV51704083; called by muse, mutect2, varscan2
- SEMA6A | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 68/692 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.321); catalogued as rs1384916387; called by muse, mutect2
- SFSWAP | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 243/579 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV55524198; called by muse, mutect2, varscan2
- TAF1 | c.2923C>T p.L975F (on ENST00000373790 / NM_138923.4; = p.L996F on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 284/742 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1227587997; called by muse, mutect2, varscan2
- TTN | c.26929G>A p.V8977I (on ENST00000591111; = p.V8050I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/355 reads (18%) | PolyPhen probably damaging (0.991); catalogued as rs368775401, COSV100615002; called by muse, mutect2, varscan2
- ZNF490 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 111/340 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as rs1314880845, COSV61009240; called by muse, mutect2, varscan2
- ARMCX3 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 96/581 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CCPG1 | c.1404G>T p.K468N | Missense Mutation (SNP) | VAF 238/542 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CREG2 | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 91/423 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- FAM171A1 | c.1832T>C p.I611T | Missense Mutation (SNP) | VAF 87/478 reads (18%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- FUT5 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 40/374 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- HERC6 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 168/733 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- HSF2 | c.524T>C p.I175T | Missense Mutation (SNP) | VAF 196/506 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- IL36G | c.148A>T p.S50C | Missense Mutation (SNP) | VAF 92/602 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ITGA8 | c.676+2T>C p.X226_splice | Splice Site (SNP) | VAF 124/278 reads (45%) | called by muse, mutect2, varscan2
- KDM4A | c.2867C>T p.P956L | Missense Mutation (SNP) | VAF 124/490 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYRFL | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 249/587 reads (42%) | SIFT tolerated (0.84); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NFATC2 | c.2149del p.S717Pfs*42 | Frame Shift Del (DEL) | VAF 58/267 reads (22%) | called by mutect2, varscan2
- NUDT11 | c.170A>G p.E57G | Missense Mutation (SNP) | VAF 80/167 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- OR2M2 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 66/846 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- RAB3GAP1 | c.2479A>C p.K827Q | Missense Mutation (SNP) | VAF 293/1250 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- RHPN2 | c.1645-3C>T | Splice Region (SNP) | VAF 124/307 reads (40%) | called by muse, mutect2, varscan2
- SBK2 | c.473_489del p.P158Rfs*? (on ENST00000344158; = p.P158Rfs*335 on NM_001370096.2) | Frame Shift Del (DEL) | VAF 38/139 reads (27%) | called by mutect2, varscan2
- SCML1 | c.62A>T p.E21V | Missense Mutation (SNP) | VAF 168/504 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TMPRSS15 | c.2794G>T p.D932Y | Missense Mutation (SNP) | VAF 81/434 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- VWF | c.7934T>C p.L2645S | Missense Mutation (SNP) | VAF 59/354 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- H2AW | c.57G>C p.S19= | Silent (SNP) | VAF 149/555 reads (27%) | called by muse, mutect2, varscan2
- MBNL3 | c.81T>C p.T27= | Silent (SNP) | VAF 74/590 reads (13%) | called by muse, mutect2, varscan2
- NCBP3 | c.1071A>G p.E357= | Silent (SNP) | VAF 204/250 reads (82%) | called by muse, mutect2, varscan2
- SERPINB2 | c.150C>T p.T50= | Silent (SNP) | VAF 86/497 reads (17%) | catalogued as rs762826443, COSV100208292; called by muse, mutect2, varscan2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 5/31 reads (16%) | catalogued as rs1262556378; called by mutect2, varscan2
- DNAAF5 | c.1931+1268G>T | Intron (SNP) | VAF 26/116 reads (22%) | called by muse, mutect2, varscan2
- GABRA6 | c.-88G>A | 5'UTR (SNP) | VAF 28/134 reads (21%) | called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- NRCAM | c.-57C>A | 5'UTR (SNP) | VAF 22/618 reads (4%) | catalogued as rs926414386, COSV100695372; called by muse, mutect2
- NRCAM | c.-58T>G | 5'UTR (SNP) | VAF 22/584 reads (4%) | called by muse, mutect2
- PIFO | c.259-83T>C | Intron (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- REEP5 | c.-6C>T | 5'UTR (SNP) | VAF 131/392 reads (33%) | catalogued as rs1473234444; called by muse, mutect2, varscan2
